Somatic mutation profile of tumor specimen HCM-WCMC-0505-C16-01A (aliquot HCM-WCMC-0505-C16-01A-11D-A79N-36) from HCMI case HCM-WCMC-0505-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.9 years (27,705 days).
Specimen HCM-WCMC-0505-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9eb005f-75d6-4cff-8ae5-041ba38f01e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0505-C16-10A (Blood Derived Normal), aliquot HCM-WCMC-0505-C16-10A-01D-A79N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99c36e19-fc90-46f6-b207-3d0777d8297e

The open-access MAF lists 276 somatic variants for this specimen: 207 protein-altering or splice-affecting, 65 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 65, Nonsense Mutation 16, Frame Shift Del 5, Intron 3, In Frame Del 3, Frame Shift Ins 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 131/295 reads (44%) | catalogued as rs387906432, CM900085, COSV64270158; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTR6 | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1247364637; called by muse, mutect2, varscan2
- ADIPOR2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 67/592 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777599853, COSV63947216; called by muse, mutect2, varscan2
- AICDA | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 214/581 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs761363877, COSV57563767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AOC3 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 114/567 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.848); catalogued as COSV53828662; called by muse, mutect2, varscan2
- ARHGEF11 | c.3625C>T p.R1209* | Nonsense Mutation (SNP) | VAF 274/623 reads (44%) | catalogued as rs1036932379, COSV59352521; called by muse, mutect2
- ASTN2 | c.1288A>G p.S430G (on ENST00000313400 / NM_001365069.1; = p.S379G on NM_014010.5) | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV100528129; called by muse, mutect2, varscan2
- B4GALNT3 | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 138/632 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1265235287; called by muse, mutect2, varscan2
- BPI | c.1159T>A p.F387I (on ENST00000262865; = p.F383I on NM_001725.3) | Missense Mutation (SNP) | VAF 31/713 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747746264; called by muse, mutect2
- C16orf95 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs747256197; called by muse, mutect2, varscan2
- C19orf44 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 187/319 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.162); catalogued as rs752225842; called by muse, mutect2, varscan2
- C2orf78 | c.2342C>A p.A781D | Missense Mutation (SNP) | VAF 230/727 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as COSV101280966; called by muse, mutect2, varscan2
- CALN1 | c.529G>A p.G177R (on ENST00000329008 / NM_001017440.3; = p.G219R on NM_031468.4) | Missense Mutation (SNP) | VAF 84/589 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV100210008; called by muse, mutect2, varscan2
- CCDC7 | c.3805G>A p.V1269I | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.003); catalogued as rs202101331; called by muse, mutect2, varscan2
- CDK9 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as rs371317161; called by muse, mutect2, varscan2
- CEP89 | c.4C>G p.L2V | Missense Mutation (SNP) | VAF 75/1300 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.121); catalogued as COSV54287600; called by muse, mutect2
- CFAP251 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 51/483 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.676); catalogued as rs1427374175; called by muse, mutect2, varscan2
- CNTNAP5 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 147/564 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as rs756574947; called by muse, mutect2, varscan2
- COL15A1 | c.3664G>T p.A1222S | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775533962; called by muse, mutect2, varscan2
- CRP | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 126/715 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs769752475, COSV99660768; called by muse, mutect2, varscan2
- CSMD3 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52235767; called by muse, mutect2, varscan2
- CUL7 | c.1837C>G p.P613A | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54819388; called by muse, mutect2, varscan2
- CYP2U1 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 99/482 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as rs763925185; called by muse, mutect2, varscan2
- DNAH17 | c.6035C>T p.S2012L | Missense Mutation (SNP) | VAF 109/312 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs752254470; called by muse, mutect2, varscan2
- EPCAM | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 73/413 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs372660671; called by muse, mutect2, varscan2
- ETF1 | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 54/969 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as rs1162351595; called by muse, mutect2
- FAM171B | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 93/427 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1344370335, COSV59003130; called by muse, mutect2, varscan2
- FLNC | c.7108G>A p.G2370S | Missense Mutation (SNP) | VAF 138/363 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as rs201917318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLYWCH1 | c.856G>A p.E286K (on ENST00000253928 / NM_001308068.2; = p.E285K on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/374 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs761336488; called by muse, mutect2, varscan2
- GOLGA4 | c.4462C>A p.L1488I | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.876); catalogued as COSV62710358; called by muse, mutect2, varscan2
- GPR6 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 268/754 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as rs955696746, COSV99254581; called by muse, varscan2
- GRM5 | c.788A>G p.K263R | Missense Mutation (SNP) | VAF 56/369 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs753432754; called by muse, mutect2, varscan2
- GSPT2 | c.1277C>G p.S426* | Nonsense Mutation (SNP) | VAF 73/344 reads (21%) | catalogued as COSV61213843; called by muse, mutect2, varscan2
- HDDC2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV59532421; called by muse, mutect2
- HMCN1 | c.7477G>T p.E2493* | Nonsense Mutation (SNP) | VAF 55/566 reads (10%) | catalogued as COSV54914603; called by muse, mutect2
- IGKV3-15 | c.157T>G p.L53V | Missense Mutation (SNP) | VAF 137/847 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs768194531; called by muse, mutect2, varscan2
- IGLV3-12 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 58/350 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs778559176; called by muse, mutect2, varscan2
- IRX2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 127/515 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs1560949733; called by muse, mutect2, varscan2
- ITGA3 | c.2501C>T p.T834M | Missense Mutation (SNP) | VAF 113/609 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs140248487; called by muse, mutect2, varscan2
- ITSN2 | c.4721A>C p.H1574P | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs751516293; called by muse, mutect2, varscan2
- KCNJ14 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 22/786 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1391388213, COSV53518065; called by muse, mutect2
- KHDRBS2 | c.617G>C p.R206P | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV55478958; called by muse, mutect2, varscan2
- KIRREL1 | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 228/1029 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs777659418; called by muse, mutect2, varscan2
- KMT2C | c.6469G>T p.D2157Y | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51293231; called by muse, mutect2, varscan2
- KRT3 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs760545335; called by muse, mutect2, varscan2
- LAMA1 | c.8069T>C p.L2690P | Missense Mutation (SNP) | VAF 201/369 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.434); catalogued as COSV99072068; called by muse, mutect2, varscan2
- LRP1B | c.4519C>T p.Q1507* | Nonsense Mutation (SNP) | VAF 58/520 reads (11%) | catalogued as COSV67259285; called by muse, mutect2, varscan2
- MAST2 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 102/275 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as rs781040322; called by muse, mutect2, varscan2
- MGAM | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 69/430 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs368879552, COSV101516582; called by muse, mutect2, varscan2
- MNDA | c.1001A>C p.K334T | Missense Mutation (SNP) | VAF 159/330 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as COSV63739844, COSV63741720; called by muse, mutect2, varscan2
- MRGPRG | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 302/556 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV60040257; called by muse, mutect2, varscan2
- MYH9 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs765414397, COSV53392407; called by muse, mutect2, varscan2
- NALCN | c.4745G>T p.R1582L | Missense Mutation (SNP) | VAF 102/334 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51954405, COSV99215015; called by muse, mutect2, varscan2
- NDRG1 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 47/372 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs756570592; called by muse, mutect2, varscan2
- NLGN3 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 124/275 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs768259710, COSV100705169; called by muse, mutect2, varscan2
- NOTCH3 | c.1298A>G p.N433S | Missense Mutation (SNP) | VAF 267/470 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658524; called by muse, mutect2, varscan2
- NRXN3 | c.3262C>T p.P1088S (on ENST00000335750 / NM_001330195.2; = p.P715S on NM_004796.6) | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1189963751; called by muse, mutect2, varscan2
- OGDHL | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 89/529 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs373974919; called by muse, mutect2, varscan2
- OR56A1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 32/437 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100360386; called by muse, mutect2
- OR6F1 | c.216G>C p.W72C | Missense Mutation (SNP) | VAF 23/424 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100129084; called by muse, mutect2
- PAQR6 | c.328C>G p.R110G (on ENST00000292291 / NM_001272108.2; = p.R4G on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/1594 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV52745613; called by muse, mutect2
- PCDHGB3 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 188/421 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1430797606, COSV53906319; called by muse, mutect2, varscan2
- PDE4DIP | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs782373842; called by mutect2, varscan2
- PLCB4 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV53804675, COSV53813316; called by muse, mutect2, varscan2
- POLR2I | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 90/807 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs752004943; called by muse, mutect2, varscan2
- RAB6B | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs1179735181, COSV99557700; called by muse, mutect2, varscan2
- RNF135 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 101/570 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs531301373, COSV60434063; called by muse, mutect2, varscan2
- RTN1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as COSV50731541; called by muse, mutect2, varscan2
- SETD1B | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 138/759 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs756584620; called by muse, mutect2, varscan2
- SHROOM2 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 221/513 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368355034, COSV66604270; called by muse, mutect2, varscan2
- SIRT1 | c.269A>C p.Q90P | Missense Mutation (SNP) | VAF 129/613 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as rs1181845230; called by muse, mutect2, varscan2
- SLC7A10 | c.1510_1512del p.E504del | In Frame Del (DEL) | VAF 324/1040 reads (31%) | catalogued as rs773962144; called by pindel, varscan2
- SMARCA4 | c.2438C>G p.S813* | Nonsense Mutation (SNP) | VAF 84/244 reads (34%) | catalogued as COSV60807773; called by muse, mutect2, varscan2
- SPTBN1 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as rs1392293475; called by muse, mutect2, varscan2
- SPTLC3 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs267605838, COSV65463320; called by muse, mutect2, varscan2
- STOX2 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs770188476; called by muse, mutect2, varscan2
- SYNDIG1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 210/1022 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as rs144760628; called by muse, varscan2
- TBX20 | c.143A>C p.K48T | Missense Mutation (SNP) | VAF 115/457 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as COSV101282375, COSV101282400; called by muse, mutect2, varscan2
- TDRD9 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 58/474 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as rs373060575; called by muse, mutect2, varscan2
- TP53 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 265/447 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52708806, COSV52766179, COSV52793434; called by muse, mutect2, varscan2
- TRPM2 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs369318694; called by muse, mutect2, varscan2
- TRPM2 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 137/709 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs767979728, COSV55971241; called by muse, mutect2, varscan2
- TTC3 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 66/332 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV61287527; called by muse, mutect2, varscan2
- TTN | c.78822A>C p.Q26274H (on ENST00000591111; = p.Q18850H on NM_003319.4) | Missense Mutation (SNP) | VAF 113/317 reads (36%) | PolyPhen benign (0.003); catalogued as COSV59950622; called by muse, mutect2, varscan2
- URI1 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 75/963 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1194138839; called by muse, mutect2
- XIRP2 | c.8445A>C p.E2815D (on ENST00000628543; = p.E2990D on NM_152381.6) | Missense Mutation (SNP) | VAF 90/312 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs1015438119; called by muse, mutect2, varscan2
- ZBTB7A | c.1447A>T p.R483* | Nonsense Mutation (SNP) | VAF 243/413 reads (59%) | catalogued as COSV99075740; called by muse, mutect2, varscan2
- ZNF785 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 258/463 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201848622, COSV67876261; called by muse, mutect2, varscan2
- ABCB1 | c.3206T>A p.V1069E | Missense Mutation (SNP) | VAF 150/1311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB4 | c.124G>C p.V42L | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- AC093155.3 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 20/434 reads (5%) | PolyPhen benign (0.009); called by muse, mutect2
- ADGB | c.1064A>G p.E355G | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL2 | c.1433A>T p.K478M | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AGTPBP1 | c.1389G>T p.E463D (on ENST00000357081 / NM_001330701.2; = p.E423D on NM_015239.2) | Missense Mutation (SNP) | VAF 54/335 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- AKAP6 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 175/385 reads (45%) | called by muse, mutect2, varscan2
- ANKRD27 | c.2319G>C p.R773S | Missense Mutation (SNP) | VAF 260/1770 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AP4E1 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ARID1B | c.2540G>T p.S847I | Missense Mutation (SNP) | VAF 269/426 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ASAP2 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 89/555 reads (16%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BMP7 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 249/1234 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- BTBD8 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C1QL2 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 207/775 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C4orf47 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CACNA1E | c.443del p.F148Sfs*39 | Frame Shift Del (DEL) | VAF 301/841 reads (36%) | called by mutect2, pindel, varscan2
- CDH19 | c.1352T>A p.I451N | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- CDT1 | c.1587_1607del p.I532_H538del | In Frame Del (DEL) | VAF 63/449 reads (14%) | called by mutect2, pindel, varscan2
- CEP350 | c.2804T>G p.F935C | Missense Mutation (SNP) | VAF 62/654 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CNBD2 | c.1403T>A p.I468K (on ENST00000373973 / NM_001365709.1; = p.I464K on NM_080834.4) | Missense Mutation (SNP) | VAF 155/576 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL3A1 | c.1082C>A p.S361* | Nonsense Mutation (SNP) | VAF 50/272 reads (18%) | called by mutect2, varscan2
- COL4A1 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 100/570 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREB3L4 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 54/774 reads (7%) | called by muse, mutect2
- CSMD2 | c.6457T>C p.Y2153H | Missense Mutation (SNP) | VAF 159/423 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK1A1L | c.32T>A p.L11H | Missense Mutation (SNP) | VAF 16/446 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.123); called by muse, mutect2
- CTTN | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 73/1300 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- DCAF12L1 | c.877A>T p.S293C | Missense Mutation (SNP) | VAF 235/515 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DGKI | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 154/356 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- DIDO1 | c.6508G>T p.D2170Y | Missense Mutation (SNP) | VAF 133/1238 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- EGFL6 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 105/207 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGR2 | c.818T>G p.L273R | Missense Mutation (SNP) | VAF 99/460 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EML5 | c.5129T>G p.L1710R (on ENST00000380664; = p.L1718R on NM_183387.3) | Missense Mutation (SNP) | VAF 65/374 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ENO3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 132/226 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- EPHA6 | c.3373_3375del p.E1125del | In Frame Del (DEL) | VAF 44/299 reads (15%) | called by mutect2, pindel, varscan2
- EPHA7 | c.2463C>A p.S821R | Missense Mutation (SNP) | VAF 129/481 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F5 | c.4342C>G p.L1448V | Missense Mutation (SNP) | VAF 95/554 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAM78B | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 368/784 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- FAT4 | c.8742del p.K2914Nfs*22 | Frame Shift Del (DEL) | VAF 35/242 reads (14%) | called by mutect2, pindel, varscan2
- FOXA2 | c.918delinsAA p.S307Kfs*55 (on ENST00000377115 / NM_153675.3; = p.S313Kfs*55 on NM_021784.5) | Frame Shift Ins (INS) | VAF 109/1279 reads (9%) | called by mutect2*, pindel
- FRK | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABPB2 | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 362/698 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GGT1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 73/401 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- GLRB | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GREB1L | c.5227C>T p.Q1743* | Nonsense Mutation (SNP) | VAF 34/936 reads (4%) | called by muse, mutect2
- GSK3B | c.913T>C p.F305L (on ENST00000264235 / NM_001146156.2; = p.F318L on NM_002093.4) | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- H1-7 | c.583A>T p.R195* | Nonsense Mutation (SNP) | VAF 36/688 reads (5%) | called by muse, mutect2
- HAO2 | c.14_26del p.C5Ffs*44 | Frame Shift Del (DEL) | VAF 116/344 reads (34%) | called by mutect2, pindel, varscan2
- HRC | c.1529A>G p.H510R | Missense Mutation (SNP) | VAF 94/635 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, varscan2
- IGKV3-11 | c.303A>C p.E101D | Missense Mutation (SNP) | VAF 145/573 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGKV6D-41 | c.297A>C p.E99D | Missense Mutation (SNP) | VAF 58/514 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- IPO13 | c.2017G>A p.G673R | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IVL | c.1028T>G p.L343R | Missense Mutation (SNP) | VAF 167/857 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- KCNA4 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 18/696 reads (3%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2
- KERA | c.512T>G p.L171R | Missense Mutation (SNP) | VAF 104/393 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF13A | c.3895T>A p.Y1299N | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- KIRREL2 | c.568A>C p.T190P | Missense Mutation (SNP) | VAF 120/767 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- KNDC1 | c.1934G>A p.G645E | Missense Mutation (SNP) | VAF 34/756 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- KNTC1 | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- LASP1 | c.258_281del p.Y86_K94delins* | Nonsense Mutation (DEL) | VAF 58/313 reads (19%) | called by mutect2, pindel, varscan2
- LGI2 | c.1220A>C p.K407T | Missense Mutation (SNP) | VAF 137/405 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- LRRC8C | c.2321G>A p.C774Y | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MALRD1 | c.4727G>C p.R1576P | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- MALRD1 | c.5948A>C p.N1983T | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MID1 | c.59del p.P20Lfs*19 | Frame Shift Del (DEL) | VAF 246/595 reads (41%) | called by mutect2, pindel, varscan2
- MIDN | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 248/446 reads (56%) | called by muse, mutect2, varscan2
- MRLN | c.37A>C p.T13P | Missense Mutation (SNP) | VAF 16/97 reads (16%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- MTUS2 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 98/353 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MYO5B | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 172/331 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NAA35 | c.1586T>G p.L529R | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NCOA3 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 250/886 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- NCOA6 | c.3155A>C p.Q1052P | Missense Mutation (SNP) | VAF 171/884 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, varscan2
- NFATC1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 258/516 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NFKBIZ | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 76/461 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- NPIPB2 | c.802C>T p.Q268* (on ENST00000399147; = p.Q128* on NM_001355514.1) | Nonsense Mutation (SNP) | VAF 54/876 reads (6%) | called by muse, mutect2
- NRXN1 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 86/555 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2T33 | c.857del p.L286Pfs*5 | Frame Shift Del (DEL) | VAF 103/365 reads (28%) | called by mutect2, pindel, varscan2
- OR9G1 | c.624C>G p.C208W | Missense Mutation (SNP) | VAF 95/851 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- PCLO | c.1790T>G p.L597R | Missense Mutation (SNP) | VAF 112/1033 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PDE6H | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 56/458 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDYN | c.25G>C p.A9P | Missense Mutation (SNP) | VAF 130/503 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- PGPEP1L | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 55/424 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PIWIL2 | c.1398A>T p.E466D | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.1844T>G p.V615G | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCD1 | c.703A>C p.T235P | Missense Mutation (SNP) | VAF 114/538 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- POT1 | c.488A>T p.D163V | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PRR14 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 91/563 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTRH2 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- RGMB | c.592C>G p.Q198E (on ENST00000513185 / NM_001366508.1; = p.Q239E on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGPD4 | c.4576T>A p.S1526T | Missense Mutation (SNP) | VAF 32/751 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- RHBDL1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 36/676 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2
- RPE | c.419T>G p.V140G (on ENST00000359429 / NM_001318926.1; = p.V90G on NM_006916.2) | Missense Mutation (SNP) | VAF 143/551 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RUSF1 | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 39/593 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SACS | c.12529dup p.Y4177Lfs*11 | Frame Shift Ins (INS) | VAF 111/483 reads (23%) | called by mutect2, pindel, varscan2
- SLC25A21 | c.787A>C p.I263L | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC8A1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 43/440 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPACA4 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 40/742 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- SPPL2A | c.478A>T p.M160L | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STYX | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYNPO | c.1356G>C p.E452D (on ENST00000394243 / NM_001166208.2; = p.E208D on NM_007286.6) | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- TGFBR2 | c.725T>G p.L242R | Missense Mutation (SNP) | VAF 98/487 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOPAZ1 | c.280T>A p.S94T | Missense Mutation (SNP) | VAF 71/459 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRGV1 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 144/496 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRGV5 | c.227T>A p.V76E | Missense Mutation (SNP) | VAF 74/443 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- TRIM23 | c.572T>A p.L191* | Nonsense Mutation (SNP) | VAF 155/334 reads (46%) | called by muse, mutect2, varscan2
- TRPA1 | c.3096A>T p.E1032D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPC4 | c.1775T>A p.F592Y | Missense Mutation (SNP) | VAF 94/354 reads (27%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UBC | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 147/519 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UNC80 | c.7362A>C p.E2454D | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- UPK1A | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 347/587 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- VPS13D | c.11528A>G p.N3843S | Missense Mutation (SNP) | VAF 69/400 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- WDR36 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB4 | c.1332C>G p.N444K | Missense Mutation (SNP) | VAF 122/711 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF473 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 85/542 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF492 | c.1487A>C p.K496T | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ZNF587B | c.600A>T p.K200N | Missense Mutation (SNP) | VAF 144/899 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ZNF606 | c.1379A>C p.K460T | Missense Mutation (SNP) | VAF 399/811 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF710 | c.1079T>G p.F360C | Missense Mutation (SNP) | VAF 90/505 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF737 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ZNRF1 | c.183dup p.S62Qfs*51 | Frame Shift Ins (INS) | VAF 234/855 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.396C>T p.R132= | Silent (SNP) | VAF 56/425 reads (13%) | called by muse, mutect2, varscan2
- ADSL | c.1398T>C p.Y466= | Silent (SNP) | VAF 88/242 reads (36%) | called by muse, mutect2, varscan2
- AEBP2 | c.1503G>A p.L501= | Silent (SNP) | VAF 14/299 reads (5%) | called by muse, mutect2
- AFF2 | c.1743T>G p.A581= | Silent (SNP) | VAF 202/459 reads (44%) | called by muse, mutect2, varscan2
- AKNA | c.3225G>A p.Q1075= | Silent (SNP) | VAF 54/351 reads (15%) | called by muse, mutect2, varscan2
- ANKS4B | c.93C>T p.D31= | Silent (SNP) | VAF 197/362 reads (54%) | catalogued as rs761541321; called by muse, mutect2, varscan2
- CCDC171 | c.3627C>G p.V1209= | Silent (SNP) | VAF 76/199 reads (38%) | called by muse, mutect2, varscan2
- CCDC185 | c.1860C>T p.N620= | Silent (SNP) | VAF 35/243 reads (14%) | called by muse, mutect2, varscan2
- CCRL2 | c.426G>A p.R142= | Silent (SNP) | VAF 79/429 reads (18%) | called by muse, mutect2, varscan2
- CES5A | c.1512C>T p.N504= (on ENST00000290567 / NM_001143685.2; = p.N454= on NM_145024.3) | Silent (SNP) | VAF 109/302 reads (36%) | catalogued as rs186119494, COSV51865025; called by muse, mutect2, varscan2
- CFAP52 | c.1545C>T p.F515= | Silent (SNP) | VAF 180/325 reads (55%) | called by muse, mutect2, varscan2
- COL12A1 | c.1182C>G p.L394= | Silent (SNP) | VAF 159/512 reads (31%) | called by muse, mutect2, varscan2
- COPS5 | c.552C>T p.G184= | Silent (SNP) | VAF 34/216 reads (16%) | catalogued as rs570152372, COSV100769935; called by muse, mutect2, varscan2
- CROT | c.1254G>A p.T418= | Silent (SNP) | VAF 70/1007 reads (7%) | catalogued as rs142498632; called by muse, mutect2
- CSAD | c.1461G>A p.E487= (on ENST00000444623 / NM_001244705.2; = p.E514= on NM_015989.5) | Silent (SNP) | VAF 84/321 reads (26%) | called by muse, mutect2, varscan2
- DICER1 | c.5196G>A p.L1732= | Silent (SNP) | VAF 88/417 reads (21%) | called by muse, mutect2, varscan2
- DIMT1 | c.579G>A p.K193= | Silent (SNP) | VAF 43/209 reads (21%) | called by muse, mutect2, varscan2
- DNAH11 | c.3114T>G p.T1038= | Silent (SNP) | VAF 59/497 reads (12%) | catalogued as COSV60937946; called by muse, mutect2, varscan2
- EIF3I | c.18G>T p.L6= | Silent (SNP) | VAF 54/308 reads (18%) | catalogued as rs1379660245; called by muse, mutect2, varscan2
- F8 | c.2766C>T p.S922= | Silent (SNP) | VAF 86/334 reads (26%) | catalogued as CD082109, COSV64278626; called by muse, mutect2, varscan2
- FOXD4 | c.378G>A p.T126= | Silent (SNP) | VAF 64/850 reads (8%) | called by muse, mutect2
- FOXD4L1 | c.387G>A p.T129= | Silent (SNP) | VAF 216/880 reads (25%) | catalogued as rs1431191267; called by muse, mutect2, varscan2
- GPR137C | c.759C>A p.V253= | Silent (SNP) | VAF 137/375 reads (37%) | called by muse, mutect2, varscan2
- HERC2 | c.11901C>A p.G3967= | Silent (SNP) | VAF 46/740 reads (6%) | called by muse, mutect2
- HEXB | c.1572C>T p.D524= | Silent (SNP) | VAF 52/272 reads (19%) | catalogued as rs770560389, COSV54666967; ClinVar: likely benign; called by muse, mutect2, varscan2
- IFNLR1 | c.444C>G p.P148= | Silent (SNP) | VAF 125/820 reads (15%) | called by muse, mutect2, varscan2
- INTS1 | c.1998G>A p.P666= | Silent (SNP) | VAF 155/966 reads (16%) | catalogued as rs1251565692; called by muse, mutect2
- JPH2 | c.1380G>A p.A460= | Silent (SNP) | VAF 220/1275 reads (17%) | catalogued as rs531877510; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- KRTAP2-4 | c.339C>T p.C113= | Silent (SNP) | VAF 150/486 reads (31%) | catalogued as rs751495363, COSV67458593; called by mutect2, varscan2
- LRRC28 | c.841C>T p.L281= | Silent (SNP) | VAF 37/339 reads (11%) | called by muse, mutect2, varscan2
- MAP7 | c.1476G>A p.E492= | Silent (SNP) | VAF 196/625 reads (31%) | called by muse, mutect2, varscan2
- MUC17 | c.3057A>G p.E1019= | Silent (SNP) | VAF 131/1282 reads (10%) | catalogued as rs1455388524, COSV60294420; called by muse, mutect2
- MYBPC2 | c.3192G>A p.S1064= | Silent (SNP) | VAF 62/394 reads (16%) | catalogued as rs750959477; called by muse, mutect2, varscan2
- MYT1 | c.3333C>T p.S1111= | Silent (SNP) | VAF 118/892 reads (13%) | catalogued as COSV60509087; called by muse, mutect2, varscan2
- NPAS3 | c.909C>T p.T303= (on ENST00000356141 / NM_001164749.2; = p.T271= on NM_022123.3) | Silent (SNP) | VAF 140/375 reads (37%) | catalogued as rs746089574; called by muse, mutect2, varscan2
- NRP2 | c.1728G>A p.E576= | Silent (SNP) | VAF 140/1031 reads (14%) | catalogued as COSV55931861; called by muse, mutect2, varscan2
- ONECUT3 | c.21C>T p.S7= | Silent (SNP) | VAF 214/370 reads (58%) | called by muse, mutect2, varscan2
- PAK3 | c.1323A>G p.P441= (on ENST00000262836 / NM_001324328.2; = p.P426= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 83/377 reads (22%) | catalogued as rs150235270; called by muse, mutect2, varscan2
- PEX2 | c.633C>T p.I211= | Silent (SNP) | VAF 175/461 reads (38%) | catalogued as COSV63813033; called by muse, mutect2, varscan2
- PNP | c.327C>T p.D109= | Silent (SNP) | VAF 60/322 reads (19%) | called by muse, mutect2, varscan2
- POLR2B | c.3381T>A p.I1127= | Silent (SNP) | VAF 21/453 reads (5%) | called by muse, mutect2
- POR | c.1227C>T p.A409= | Silent (SNP) | VAF 43/1432 reads (3%) | catalogued as rs782563724; called by muse, mutect2
- PPP2R3A | c.3171T>C p.N1057= | Silent (SNP) | VAF 67/370 reads (18%) | called by muse, mutect2, varscan2
- PTCD3 | c.1071A>G p.L357= | Silent (SNP) | VAF 144/373 reads (39%) | called by muse, mutect2, varscan2
- RALBP1 | c.1257G>T p.G419= | Silent (SNP) | VAF 38/214 reads (18%) | called by mutect2, varscan2
- SHANK1 | c.4089G>A p.A1363= | Silent (SNP) | VAF 87/572 reads (15%) | called by muse, mutect2, varscan2
- SHD | c.189C>A p.S63= | Silent (SNP) | VAF 81/694 reads (12%) | called by muse, mutect2, varscan2
- SLC4A10 | c.924A>T p.G308= | Silent (SNP) | VAF 16/441 reads (4%) | called by muse, mutect2
- SLCO5A1 | c.1527C>T p.I509= | Silent (SNP) | VAF 87/489 reads (18%) | catalogued as COSV99480286; called by muse, mutect2, varscan2
- SPATA31A7 | c.1221T>C p.S407= | Silent (SNP) | VAF 95/286 reads (33%) | called by muse, mutect2, varscan2
- SYNE1 | c.13479C>G p.V4493= (on ENST00000367255 / NM_182961.4; = p.V4422= on NM_033071.3) | Silent (SNP) | VAF 107/461 reads (23%) | called by muse, mutect2, varscan2
- SYNPO2 | c.531C>T p.R177= | Silent (SNP) | VAF 141/409 reads (34%) | catalogued as rs139521362; called by muse, mutect2, varscan2
- TAS2R19 | c.816T>G p.P272= | Silent (SNP) | VAF 115/940 reads (12%) | called by muse, mutect2, varscan2
- TEP1 | c.426C>T p.Y142= | Silent (SNP) | VAF 27/534 reads (5%) | catalogued as COSV52995958; called by muse, mutect2
- TLE1 | c.963G>T p.T321= | Silent (SNP) | VAF 103/483 reads (21%) | called by muse, mutect2, varscan2
- TRBJ2-4 | c.36C>G p.T12= | Silent (SNP) | VAF 114/540 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.95679A>G p.K31893= (on ENST00000591111; = p.K24469= on NM_003319.4) | Silent (SNP) | VAF 131/384 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.8205C>T p.V2735= (on ENST00000591111; = p.V2689= on NM_003319.4) | Silent (SNP) | VAF 32/464 reads (7%) | called by muse, mutect2
- TTN | c.6594T>C p.T2198= (on ENST00000591111; = p.T2152= on NM_003319.4) | Silent (SNP) | VAF 121/340 reads (36%) | catalogued as COSV100592265; called by muse, mutect2, varscan2
- USP42 | c.3681C>T p.D1227= | Silent (SNP) | VAF 94/475 reads (20%) | catalogued as rs887759670; called by muse, mutect2, varscan2
- WNK2 | c.2394T>C p.I798= | Silent (SNP) | VAF 87/460 reads (19%) | catalogued as rs1430134543; called by muse, mutect2, varscan2
- ZNF354C | c.642A>G p.K214= | Silent (SNP) | VAF 95/227 reads (42%) | called by muse, mutect2, varscan2
- ZNF471 | c.1062T>G p.A354= | Silent (SNP) | VAF 161/360 reads (45%) | called by muse, mutect2, varscan2
- ZNF804B | c.204G>A p.Q68= | Silent (SNP) | VAF 54/952 reads (6%) | catalogued as COSV60825097; called by muse, mutect2
- ZNF814 | c.1731G>T p.G577= | Silent (SNP) | VAF 763/978 reads (78%) | called by muse, mutect2, varscan2
- ABHD5 | c.774-734G>A | Intron (SNP) | VAF 135/324 reads (42%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+2073C>T | Intron (SNP) | VAF 52/286 reads (18%) | called by muse, mutect2, varscan2
- DNAJA4 | c.132+707C>T | Intron (SNP) | VAF 119/338 reads (35%) | called by muse, mutect2, varscan2
- RNU6-784P | chr4:70705023 G>C | 5'Flank (SNP) | VAF 103/781 reads (13%) | called by muse, mutect2, varscan2
